Gene-level copy-number profile of tumor specimen TCGA-35-5375-01A from TCGA case TCGA-35-5375, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.0 years (22,628 days).
Specimen TCGA-35-5375-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.34a3a3ea-d348-4858-8d72-fba8923c5ead.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-35-5375-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72e4d040-6487-401c-9d5c-0b7e1c4e86ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 158; copy number 1: 5,549; copy number 2: 5,419; copy number 3: 5,542; copy number 4: 15,146; copy number 5: 9,853; copy number 6: 4,319; copy number 7: 7,442; copy number 8: 4,429; copy number 9: 406; copy number 10: 602; copy number 11: 573; copy number 12: 9; copy number 13: 20; copy number 15: 205; copy number 16: 65; copy number 17: 73; copy number 26: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-35-5375-01A-01D-1624-01): tumor purity 0.58, ploidy 3.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 158 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:148,078,762–148,444,698, 1 gene (within-gene range 0–3): NR3C2.
- chr4:148,526,493–148,694,323, 3 genes: ASS1P8, RNA5SP166, AC108935.1.
- chr13:68,289,679–83,298,167, 154 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,954 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,972,712–181,182,208, 4 genes, copy number 11 (within-gene range 6–11): STX6, MR1, IER5, LINC01732.
- chr2:82,831,234–83,219,105, 3 genes, copy number 15 (within-gene range 8–15): AC098817.1, DHFRP3, AC138623.1.
- chr3:96,244,732–114,103,628, 271 genes, copy number 10 (broad region; genes not listed).
- chr3:193,274,789–193,378,820, 1 gene, copy number 10 (within-gene range 7–10): ATP13A5.
- chr3:193,398,967–194,287,368, 23 genes, copy number 10: ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048.
- chr5:218,298–45,895,970, 702 genes, copy number 10–17 (within-gene range 6–17) (broad region; genes not listed).
- chr7:12,211,270–12,700,889, 13 genes, copy number 10–26: TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1.
- chr8:121,113,358–125,091,819, 82 genes, copy number 9 (broad region; genes not listed).
- chr11:48,216,810–55,607,645, 111 genes, copy number 9 (broad region; genes not listed).
- chr14:18,333,726–25,050,297, 475 genes, copy number 11–15 (broad region; genes not listed).
- chr14:33,924,227–34,675,994, 15 genes, copy number 13 (within-gene range 8–13): EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P.
- chr17:21,592,794–27,058,221, 41 genes, copy number 10: AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2, AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P.
- chr20:87,250–8,043,512, 211 genes, copy number 9 (broad region; genes not listed).
- chr20:8,097,824–8,256,918, 2 genes, copy number 9: PHKBP1, PLCB1-IT1.

Autosomal genes at a single copy (total copy number 1): 5,549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
